Gene-level copy-number profile of tumor specimen TCGA-CC-A5UC-01A from TCGA case TCGA-CC-A5UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.4 years (23,156 days).
Specimen TCGA-CC-A5UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f2ae6ea8-cc31-4b81-b748-edc0b67d7dfe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A5UC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/341f311c-7bd7-4f1b-95eb-d87cb7ef9b2d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 13,686; copy number 2: 43,118; copy number 3: 3,006.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A5UC-01A-11D-A28W-01): tumor purity 0.29, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,355,529–78,553,296, 5 genes: LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
